Somatic mutation profile of tumor specimen C3L-00189-01 (aliquot CPT0081060010) from CPTAC case C3L-00189, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.3 years (24,958 days).
Specimen C3L-00189-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00b3d0b1-dff4-41c0-9768-bcd4b349e9d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00189-31 (Blood Derived Normal), aliquot CPT0081100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fcd0bc1-85c9-4be6-ae20-8c99ed49743f

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 24/340 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SNX25 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1265568494; called by muse, mutect2
- STXBP5 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99468674; called by muse, mutect2
- CCDC186 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRYBB3 | c.206T>G p.F69C | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DYNC2H1 | c.12453A>G p.I4151M | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2
- GBX1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2
- SEMA3E | c.402T>C p.G134= | Silent (SNP) | VAF 22/475 reads (5%) | called by muse, mutect2
- SLC9A7 | c.1995C>T p.Y665= | Silent (SNP) | VAF 22/530 reads (4%) | catalogued as rs1444255492, COSV100092100; called by muse, mutect2
